Somatic mutation profile of tumor specimen MMRF_1446_2_BM_CD138pos (aliquot MMRF_1446_2_BM_CD138pos_T1_KHS5U_L12891) from MMRF case MMRF_1446, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,147 days).
Specimen MMRF_1446_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a066a1f8-bfda-4d0f-9de0-74a46ef95b40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1446_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1446_1_PB_Whole_C2_KAS5U_L01386; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf0d5669-0d0b-4aff-a777-c4c6e48b852a

The open-access MAF lists 52 somatic variants for this specimen: 21 protein-altering or splice-affecting, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, 3'UTR 17, Intron 6, 5'UTR 4, 5'Flank 3, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777369534, COSV67133581; called by muse, mutect2
- AL121899.2 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV67349873; called by muse, mutect2, varscan2
- NUP160 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 28/477 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs373309220; called by muse, mutect2
- PDZD8 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1203020332; called by muse, mutect2
- PLXNB3 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT tolerated (0.76); PolyPhen benign (0.048); catalogued as rs781926148; called by muse, mutect2, varscan2
- TGM6 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs774913444, COSV52479333; called by muse, mutect2, varscan2
- TNFRSF8 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs193921033, COSV55799349; called by muse, mutect2, varscan2
- AADAC | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BABAM2 | c.924del p.V310Yfs*80 (on ENST00000342045 / NM_001329115.1; = p.V310Yfs*138 on NM_004899.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 53/127 reads (42%) | called by mutect2, pindel, varscan2
- CHD8 | c.5921C>T p.A1974V (on ENST00000646647 / NM_001170629.2; = p.A1695V on NM_020920.4) | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EFHC1 | c.1855A>T p.T619S | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2
- GRIP2 | c.792del p.H264Qfs*12 (on ENST00000619221; = p.H167Qfs*12 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 87/188 reads (46%) | called by mutect2, pindel, varscan2
- IGHD5-24 | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.334A>C p.S112R | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- IMPDH1 | c.908T>G p.V303G (on ENST00000470772 / NM_001142573.2; = p.V389G on NM_000883.4) | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LRRC74B | c.285C>A p.G95= | Splice Region (SNP) | VAF 28/70 reads (40%) | called by muse, varscan2
- MAGEC3 | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2
- SNX7 | c.911A>C p.D304A | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TAS1R1 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TENT5C | c.910T>C p.Y304H | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC37 | c.4475T>A p.F1492Y | Missense Mutation (SNP) | VAF 138/296 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACTN1 | c.-364G>T | 5'UTR (SNP) | VAF 94/111 reads (85%) | called by muse, mutect2, varscan2
- AKR1D1 | c.*356A>G | 3'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505379 ins CCCTG | 5'Flank (INS) | VAF 49/141 reads (35%) | called by mutect2, pindel, varscan2
- C4orf50 | c.*2151G>A | 3'UTR (SNP) | VAF 40/104 reads (38%) | catalogued as rs1039983231; called by muse, mutect2, varscan2
- CAMK1D | c.*5026T>A | 3'UTR (SNP) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- CD6 | c.*699C>G | 3'UTR (SNP) | VAF 69/149 reads (46%) | called by muse, mutect2, varscan2
- CFAP61 | c.567-5334A>G | Intron (SNP) | VAF 73/157 reads (46%) | catalogued as rs374326179; called by muse, mutect2, varscan2
- CPNE4 | c.*91C>G | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- DMXL2 | c.-155G>A | 5'UTR (SNP) | VAF 85/145 reads (59%) | called by muse, mutect2, varscan2
- HSPA12A | c.*2820C>A | 3'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, varscan2
- INHBB | c.*662C>G | 3'UTR (SNP) | VAF 80/176 reads (45%) | called by muse, mutect2, varscan2
- LYPD1 | c.*1230G>A | 3'UTR (SNP) | VAF 24/54 reads (44%) | catalogued as rs948261088; called by muse, varscan2
- MBP | c.576+1658A>G | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- MXD1 | c.*1287T>C | 3'UTR (SNP) | VAF 50/105 reads (48%) | catalogued as rs763140737; called by muse, mutect2, varscan2
- OTUD6B | c.-5T>C | 5'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- P3H3 | c.985+192C>A | Intron (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- PCMTD1 | c.*1584T>C | 3'UTR (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- PITRM1 | c.791+108A>T | Intron (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- PRR12 | chr19:49595051 G>A | 5'Flank (SNP) | VAF 93/196 reads (47%) | catalogued as rs374873072; called by muse, mutect2, varscan2
- PTPRK | chr6:128520562 G>A | 5'Flank (SNP) | VAF 66/154 reads (43%) | called by muse, mutect2, varscan2
- SCART1 | c.*211T>G | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- SCART1 | c.*308T>C | 3'UTR (SNP) | VAF 38/77 reads (49%) | called by muse, mutect2, varscan2
- SKIDA1 | c.-352T>C | 5'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- SLC25A36 | c.*3023T>G | 3'UTR (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- SPATS2L | c.39+4005C>T | Intron (SNP) | VAF 51/121 reads (42%) | catalogued as rs1347856615; called by muse, mutect2, varscan2
- STAG2 | chrX:124101732 T>G | 3'Flank (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- STPG2 | c.*2163G>T | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, varscan2
- TNFRSF1B | c.*315C>T | 3'UTR (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- TRIM6 | c.*1023C>G | 3'UTR (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- VGLL3 | c.937+6179G>T | Intron (SNP) | VAF 10/265 reads (4%) | called by muse, mutect2
- YWHAZ | c.*464T>A | 3'UTR (SNP) | VAF 61/143 reads (43%) | called by muse, mutect2, varscan2
